Gene-level copy-number profile of specimen HCM-BROD-0678-C71-85A from HCMI case HCM-BROD-0678-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (445 days).
Specimen HCM-BROD-0678-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 115602d1-ec8c-48b7-a527-551244708e3d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0678-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/19c18618-efd0-44fa-a7bd-154c2191e3b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,587; copy number 2: 53,028; copy number 3: 2,291; copy number 76: 3; copy number 77: 2; copy number 84: 1; copy number 155: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,072,694–127,227,541, 1 gene, copy number 84 (within-gene range 2–84): CASC19.
- chr8:127,289,817–127,742,951, 7 genes, copy number 76–155: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr8:128,220,504–128,564,679, 2 genes, copy number 77: RN7SKP226, LINC00824.

Autosomal genes at a single copy (total copy number 1): 731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
